Somatic mutation profile of tumor specimen SM-JU33M (aliquot 7316UP-3639) from CPTAC case C1245129, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen SM-JU33M: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c9c9d2e7-8ddf-4867-a2d5-b891db7f4c5a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105282 (Blood Derived Normal), aliquot 7316UP-2923-1105282; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35216aea-7b2b-49c4-a5ba-c6b391669a9a

The open-access MAF lists 55 somatic variants for this specimen: 44 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 5, 3'UTR 3, RNA 2, Frame Shift Del 2, Nonsense Mutation 1, Splice Region 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.775G>T p.D259Y | Missense Mutation (SNP) | VAF 65/335 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as rs1567548929, COSV52662086, COSV52675732, COSV52773165, COSV52962390; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.887T>C p.V296A | Missense Mutation (SNP) | VAF 48/487 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV55960968; called by muse, mutect2
- BIN3 | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 19/316 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs73671219; called by muse, mutect2
- BLK | c.918G>C p.E306D | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as COSV52056465; called by muse, mutect2
- CD1A | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 33/368 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs140989108, COSV56860759; called by muse, mutect2
- CDH18 | c.1913G>A p.R638H | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs565236156, COSV56907812, COSV99932062; called by muse, mutect2
- DOCK8 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 45/514 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.029); catalogued as rs1227911560, COSV66634653; ClinVar: uncertain significance; called by muse, mutect2
- HHLA1 | c.1295C>A p.P432Q | Missense Mutation (SNP) | VAF 26/280 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.16); catalogued as rs1368020543; called by muse, mutect2
- KIF14 | c.2461A>G p.K821E | Missense Mutation (SNP) | VAF 26/348 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV100950850; called by muse, mutect2
- LARP1 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 41/458 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs757070815, COSV60430890; called by muse, mutect2
- MYO1G | c.2457G>C p.M819I | Missense Mutation (SNP) | VAF 26/323 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.222); catalogued as rs767722811, COSV99348404; called by muse, mutect2
- NF1 | c.6645A>G p.A2215= (on ENST00000358273 / NM_001042492.3; = p.A2194= on NM_000267.3) | Splice Region (SNP) | VAF 36/571 reads (6%) | catalogued as CD076853; called by muse, mutect2
- PCDHGA6 | c.1922G>A p.S641N | Missense Mutation (SNP) | VAF 61/572 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.044); catalogued as rs1265900699, COSV53948522; called by muse, mutect2, varscan2
- PROKR1 | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 36/434 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as rs769294148; called by muse, mutect2
- PTEN | c.143A>G p.N48S | Missense Mutation (SNP) | VAF 26/220 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV64291337, COSV64303263; called by muse, mutect2, varscan2
- SAMD3 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 17/226 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1188118842, COSV60774329; called by muse, mutect2
- TRPC7 | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 30/534 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as COSV61465068; called by muse, mutect2
- VPS33B | c.1375G>A p.V459M | Missense Mutation (SNP) | VAF 43/502 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.287); catalogued as COSV60979239; called by muse, mutect2
- ACAP2 | c.1521_1526del p.Y507_E509delins* | Nonsense Mutation (DEL) | VAF 22/180 reads (12%) | called by mutect2, pindel
- ARHGEF9 | c.1465T>A p.S489T | Missense Mutation (SNP) | VAF 37/287 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BBS10 | c.958A>T p.S320C | Missense Mutation (SNP) | VAF 32/318 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.249); called by muse, mutect2
- BPTF | c.2618A>T p.K873M | Missense Mutation (SNP) | VAF 16/345 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CFAP54 | c.2804G>C p.W935S | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ECM2 | c.378C>G p.C126W | Missense Mutation (SNP) | VAF 43/451 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GIGYF2 | c.2325A>T p.E775D | Missense Mutation (SNP) | VAF 42/438 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2
- GLCCI1 | c.1438T>G p.S480A | Missense Mutation (SNP) | VAF 39/453 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.015); called by muse, mutect2
- GPR22 | c.974G>T p.C325F | Missense Mutation (SNP) | VAF 28/332 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); called by muse, mutect2
- GZF1 | c.180del p.F60Lfs*20 | Frame Shift Del (DEL) | VAF 10/102 reads (10%) | called by mutect2, pindel
- KCNQ3 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); called by muse, mutect2
- LIN52 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 12/161 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); called by muse, mutect2
- LRRC37A3 | c.2297C>G p.S766C | Missense Mutation (SNP) | VAF 70/1024 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); called by muse, mutect2
- MKI67 | c.4849T>C p.S1617P | Missense Mutation (SNP) | VAF 30/443 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- MMP12 | c.976C>A p.P326T | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ODF3 | c.205C>A p.R69S | Missense Mutation (SNP) | VAF 65/463 reads (14%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCDH11X | c.1061C>A p.S354Y | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- PIWIL1 | c.879T>G p.H293Q | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT tolerated (0.72); PolyPhen benign (0.001); called by muse, mutect2
- PLEKHA8 | c.1419G>C p.K473N | Missense Mutation (SNP) | VAF 38/423 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.062); called by muse, mutect2
- POLH | c.1135del p.S379Afs*17 | Frame Shift Del (DEL) | VAF 37/367 reads (10%) | called by mutect2, pindel, varscan2
- SNX13 | c.1042A>G p.I348V | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.122); called by muse, mutect2
- SPIN3 | c.444G>T p.R148S | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- TACC2 | c.3875C>G p.A1292G | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2
- TDRD6 | c.3350A>T p.E1117V | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.347); called by muse, mutect2
- TTC3 | c.134_144+6del p.X45_splice | Splice Site (DEL) | VAF 13/140 reads (9%) | called by mutect2, pindel
- ZNF671 | c.1499T>C p.V500A | Missense Mutation (SNP) | VAF 31/261 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- BRSK1 | c.945G>T p.L315= | Silent (SNP) | VAF 28/308 reads (9%) | catalogued as COSV58667667; called by muse, mutect2
- KCNA5 | c.642C>T p.R214= | Silent (SNP) | VAF 74/790 reads (9%) | catalogued as COSV99364284; called by muse, mutect2
- PCDHAC2 | c.147A>G p.P49= | Silent (SNP) | VAF 34/423 reads (8%) | called by muse, mutect2
- PLCH1 | c.4629C>T p.T1543= (on ENST00000340059 / NM_001130960.2; = p.T1535= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/340 reads (7%) | catalogued as rs374800898, COSV58185384; called by muse, mutect2
- SUSD3 | c.537C>T p.H179= | Silent (SNP) | VAF 30/257 reads (12%) | catalogued as rs556738504; called by muse, mutect2, varscan2
- ADAM21P1 | n.1140C>T | RNA (SNP) | VAF 34/409 reads (8%) | catalogued as rs755338109; called by muse, mutect2
- AHSA2P | n.1588C>T | RNA (SNP) | VAF 46/506 reads (9%) | called by muse, mutect2
- ALAS2 | c.*28C>A | 3'UTR (SNP) | VAF 25/108 reads (23%) | called by muse, mutect2
- CTDSPL | c.*1734G>A | 3'UTR (SNP) | VAF 30/321 reads (9%) | called by muse, mutect2
- POLD4 | c.*10T>A | 3'UTR (SNP) | VAF 10/110 reads (9%) | catalogued as rs1244054357; called by muse, mutect2, varscan2
- RTEL1 | c.958+23C>T | Intron (SNP) | VAF 19/206 reads (9%) | called by muse, mutect2
